FM case AD17658 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mucoepidermoid Neoplasms; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/243cd41b-e8a7-44c4-9d9b-0b1bd6c2da87

Female, 39.8 years: Mucoepidermoid carcinoma (ICD-O-3 8430/3) of the head, face or neck; specimen biopsied or resected from the mouth. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
